Somatic mutation profile of tumor specimen TCGA-VQ-A8E0-01A (aliquot TCGA-VQ-A8E0-01A-11D-A410-08) from TCGA case TCGA-VQ-A8E0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,848 days).
Specimen TCGA-VQ-A8E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40e8765d-435c-42b5-b4a8-b549936d99ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8E0-10B (Blood Derived Normal), aliquot TCGA-VQ-A8E0-10B-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0794f222-a101-401e-b098-026b4ec054b4

The open-access MAF lists 105 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 20, Nonsense Mutation 8, Frame Shift Ins 2, Intron 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLRN1 | c.502dup p.I168Nfs*5 (on ENST00000327047 / NM_174878.3; = p.I92Nfs*5 on NM_052995.2) | Frame Shift Ins (INS) | VAF 15/105 reads (14%) | catalogued as rs746523071; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A2M | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs576930283, COSV100588341, COSV100588832; called by muse, mutect2, varscan2
- ABCA13 | c.5698C>A p.L1900I | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.797); catalogued as COSV101329880, COSV70026424; called by muse, mutect2, varscan2
- ABLIM1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs956953836, COSV99521188; called by muse, mutect2, varscan2
- AC139530.2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs139191949; called by muse, mutect2, varscan2
- ADAMTS1 | c.362C>A p.A121E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV99535714; called by muse, mutect2, varscan2
- ADAMTS8 | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99960183; called by muse, mutect2, varscan2
- AHNAK | c.6865G>T p.E2289* | Nonsense Mutation (SNP) | VAF 90/538 reads (17%) | catalogued as COSV99945132, COSV99949132; called by muse, mutect2, varscan2
- ANO2 | c.850C>T p.R284C (on ENST00000356134 / NM_001278597.3; = p.R288C on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1214934107, COSV59028614; called by muse, mutect2, varscan2
- AREL1 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV62668798; called by muse, mutect2, varscan2
- ATAD3A | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100185954; called by muse, varscan2
- ATP6V0A4 | c.2065T>C p.S689P | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs754412161, COSV100022422; called by muse, mutect2, varscan2
- CAVIN1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100824489; called by muse, mutect2, varscan2
- CDH17 | c.944A>C p.E315A | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV99216768; called by muse, mutect2, varscan2
- CDH17 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99216770; called by muse, mutect2, varscan2
- CDON | c.523A>T p.N175Y | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99700360; called by muse, mutect2, varscan2
- CEP170B | c.2378C>T p.P793L (on ENST00000453495; = p.P722L on NM_015005.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV101371365; called by muse, mutect2, varscan2
- COL1A1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1348617517, COSV99866102; called by muse, mutect2, varscan2
- COL5A3 | c.4894C>A p.Q1632K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1454746601, COSV99317989; called by muse, mutect2, varscan2
- CTC1 | c.1866A>C p.Q622H | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100236033, COSV100236533; called by muse, mutect2, varscan2
- DDX43 | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs1562287271, COSV100943882; called by muse, mutect2, varscan2
- DHX8 | c.3052T>G p.F1018V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99291795; called by muse, mutect2, varscan2
- EPB41L4A | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99812395; called by muse, mutect2, varscan2
- EVC | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376396220; called by muse, mutect2, varscan2
- F8 | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs913744442, COSV100811208; called by muse, mutect2, varscan2
- FAM234B | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 146/484 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV99545251; called by muse, mutect2, varscan2
- FOXG1 | c.808A>C p.T270P | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100486435; called by muse, mutect2, varscan2
- FRY | c.4543C>T p.P1515S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968665; called by muse, mutect2, varscan2
- FUCA2 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99135949; called by muse, mutect2, varscan2
- GOLGA4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 76/209 reads (36%) | catalogued as rs770966777, COSV62711496; called by muse, mutect2, varscan2
- HEBP1 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99185715; called by muse, mutect2, varscan2
- HERC1 | c.9314A>T p.D3105V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV101496276; called by muse, mutect2, varscan2
- ITIH5 | c.1826C>G p.A609G | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99903323; called by muse, mutect2, varscan2
- KIF4B | c.840C>A p.D280E | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV101469142; called by muse, mutect2, varscan2
- LGALS8 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99436126; called by muse, mutect2, varscan2
- LGR4 | c.1487A>C p.Q496P | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101003788; called by muse, mutect2, varscan2
- LRRK2 | c.7211C>A p.S2404* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100108627; called by muse, mutect2, varscan2
- MAP3K21 | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs574425452, COSV100786059; called by muse, mutect2, varscan2
- MAPK10 | c.943G>A p.A315T (on ENST00000359221 / NM_001351625.2; = p.A353T on NM_002753.5) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775333978, COSV100173474; called by muse, mutect2, varscan2
- MKI67 | c.7937T>C p.L2646S | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.511); catalogued as COSV100895999; called by muse, mutect2, varscan2
- MMP16 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV54186014; called by muse, mutect2, varscan2
- OLFM4 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs775118318, COSV99524133; called by muse, mutect2, varscan2
- OR1C1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV101376160, COSV68716034; called by muse, mutect2
- OR51V1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as rs746029384, COSV100343101; called by muse, mutect2, varscan2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2, varscan2
- OR6K3 | c.193G>A p.V65I (on ENST00000368146; = p.V49I on NM_001005327.2) | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV63746802, COSV63746853; called by muse, mutect2, varscan2
- OR7C1 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); catalogued as COSV99934737; called by muse, mutect2, varscan2
- PANK3 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496145; called by muse, mutect2, varscan2
- PCDH11Y | c.883C>A p.P295T (on ENST00000400457 / NM_032973.2; = p.P284T on NM_032971.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as COSV99290219; called by mutect2, varscan2
- PCSK4 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs762489541, COSV99960519; called by muse, mutect2, varscan2
- PI4K2A | c.548G>C p.C183S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101034034; called by muse, mutect2, varscan2
- PNMA8B | c.1861G>T p.G621W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs866217322, COSV100885258; called by muse, mutect2, varscan2
- PON3 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 170/274 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV99672210; called by muse, mutect2, varscan2
- PSMC3 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100099192; called by muse, mutect2, varscan2
- PZP | c.1909C>A p.Q637K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs1162066481, COSV99735471; called by muse, mutect2, varscan2
- RESF1 | c.3136G>T p.A1046S | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100439992; called by muse, mutect2, varscan2
- RPL9 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99787487; called by muse, mutect2, varscan2
- SATB1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as rs867226721, COSV100112771; called by muse, mutect2, varscan2
- SH3GL3 | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195558; called by muse, mutect2
- SLC12A7 | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99369104; called by muse, mutect2, varscan2
- SLC27A6 | c.1692G>T p.M564I | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV52483902, COSV99321937; called by muse, mutect2, varscan2
- SNTN | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV100662579; called by muse, mutect2, varscan2
- SPAG17 | c.282dup p.P95Tfs*5 | Frame Shift Ins (INS) | VAF 66/180 reads (37%) | catalogued as rs771461785; called by mutect2, varscan2
- SPTA1 | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100934011; called by muse, mutect2, varscan2
- SYNM | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs376246829, COSV60367637; called by muse, mutect2, varscan2
- TAOK1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913348; called by muse, mutect2
- TBC1D32 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV99249145; called by muse, mutect2, varscan2
- TDRD6 | c.3697A>T p.T1233S | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.05); catalogued as COSV100286953; called by muse, mutect2, varscan2
- TIGD5 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV100363920; called by muse, mutect2, varscan2
- TLL1 | c.2297A>G p.K766R | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.986); catalogued as COSV99285611; called by muse, mutect2, varscan2
- TMEM184A | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs200028247, COSV52472232, COSV52475858; called by muse, mutect2, varscan2
- TNFRSF21 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV99728960; called by muse, mutect2, varscan2
- TNFSF13B | c.132C>G p.D44E | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.436); catalogued as COSV101022306, COSV65515699; called by muse, mutect2, varscan2
- TRIL | c.1207T>C p.Y403H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100538636; called by muse, mutect2, varscan2
- TSHZ2 | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 479/752 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100295110, COSV61590299; called by muse, mutect2, varscan2
- TSTD2 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV100358895; called by muse, mutect2
- UBE2O | c.3725G>A p.R1242Q | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs754218354, COSV100039089, COSV100039664; called by muse, mutect2, varscan2
- WASHC2C | c.3163G>A p.E1055K (on ENST00000336378; = p.E1034K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1180693308; called by muse, mutect2, varscan2
- ZNF107 | c.845A>C p.N282T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.283); catalogued as COSV100788150; called by muse, mutect2
- ZNF567 | c.1716G>T p.R572S (on ENST00000536254 / NM_001322913.1; = p.R541S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV100658592, COSV62446801; called by muse, mutect2, varscan2
- ZNF846 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as rs751764432, COSV101194244; called by muse, mutect2, varscan2
- TP53 | c.1174_1181del p.S392Tfs*76 | Frame Shift Del (DEL) | VAF 63/184 reads (34%) | called by mutect2, pindel, varscan2
- ARHGEF39 | c.639G>A p.L213= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100526141; called by muse, mutect2, varscan2
- ARID4B | c.843A>G p.E281= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs767085397, COSV99934741; called by muse, mutect2, varscan2
- EXPH5 | c.1467C>T p.F489= | Silent (SNP) | VAF 39/216 reads (18%) | catalogued as rs750363141, COSV99760715; called by muse, mutect2, varscan2
- FBXO47 | c.72C>T p.T24= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs1392288078, COSV100960504; called by muse, mutect2, varscan2
- GPR153 | c.492C>T p.I164= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs756735393, COSV100928426; called by muse, mutect2, varscan2
- HDLBP | c.3798C>T p.P1266= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99237026; called by muse, mutect2, varscan2
- HGSNAT | c.321C>T p.H107= | Silent (SNP) | VAF 94/197 reads (48%) | catalogued as rs571883806, COSV65535608; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLF5 | c.1308G>A p.G436= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as COSV100890469, COSV66615331; called by muse, mutect2, varscan2
- MYO15A | c.4554C>T p.I1518= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99230627; called by muse, mutect2
- PITX1 | c.393G>A p.P131= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs766860676, COSV99530451; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1386G>A p.Q462= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV100982279; called by muse, mutect2
- PTGDR | c.309G>A p.S103= | Silent (SNP) | VAF 113/335 reads (34%) | catalogued as rs552490333, COSV100035386, COSV60095276; called by muse, mutect2, varscan2
- PZP | c.1128C>T p.P376= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV99735477; called by muse, mutect2
- RFXAP | c.753G>A p.Q251= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99715096; called by muse, mutect2, varscan2
- SEPTIN14 | c.477C>T p.H159= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs757284369, COSV101193145; called by muse, varscan2
- TAS1R3 | c.1332C>T p.F444= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1031598850, COSV100229167; called by muse, mutect2, varscan2
- TNFSF11 | c.345A>G p.S115= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1240331546, COSV99520177; called by muse, mutect2, varscan2
- TRPA1 | c.81C>T p.D27= | Silent (SNP) | VAF 72/246 reads (29%) | catalogued as rs375901621; called by muse, mutect2, varscan2
- TTN | c.38502A>G p.A12834= (on ENST00000591111; = p.A5410= on NM_003319.4) | Silent (SNP) | VAF 112/183 reads (61%) | catalogued as COSV100588761; called by muse, mutect2, varscan2
- VLDLR | c.639C>T p.D213= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs779155452, COSV101173199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPAL2 | n.2T>C | RNA (SNP) | VAF 54/295 reads (18%) | catalogued as rs779852365; called by muse, mutect2, varscan2
- PCID2 | c.266+115T>G | Intron (SNP) | VAF 34/180 reads (19%) | catalogued as COSV99872173; called by muse, mutect2, varscan2
- USP49 | c.1876+9G>A | Intron (SNP) | VAF 48/165 reads (29%) | catalogued as rs375558993; called by muse, mutect2, varscan2
